Gene-level copy-number profile of tumor specimen TCGA-44-6775-01A from TCGA case TCGA-44-6775, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.3 years (26,415 days).
Specimen TCGA-44-6775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.47450c40-2d13-4b10-a7c6-7568270dfbec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6775-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e49f61e-ff49-4cd6-98fd-e59234eccd71

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 927; copy number 2: 8,661; copy number 3: 24,216; copy number 4: 17,452; copy number 5: 5,612; copy number 6: 1,025; copy number 7: 5; copy number 8: 1,919.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-6775-01A-11D-A273-01): tumor purity 0.27, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,924 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr7:70,972–57,777,521, 1,070 genes, copy number 8 (broad region; genes not listed).
- chr8:96,645,242–97,277,928, 5 genes, copy number 7: CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5.
- chr8:98,371,228–98,942,827, 1 gene, copy number 8 (within-gene range 2–8): STK3.
- chr8:98,603,253–102,124,907, 85 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:9,505,180–9,530,524, 2 genes, copy number 8: LAMP5-AS1, LAMP5.
- chr20:9,562,941–9,577,689, 2 genes, copy number 8: AL353612.2, AL353612.1.
- chr20:22,220,554–23,711,406, 49 genes, copy number 8: AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1.

Autosomal genes at a single copy (total copy number 1): 927. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
